Somatic mutation profile of tumor specimen MP2PRT-PARSLF-TMP1-A (aliquot MP2PRT-PARSLF-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PARSLF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 4.4 years (1,606 days).
Specimen MP2PRT-PARSLF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c162f3b-5c7f-4c12-a042-339577327c1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARSLF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARSLF-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/451c7b2a-56f2-4470-82ed-6bafd6371c23

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Nonsense Mutation 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALB | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs370819889; called by muse, mutect2, varscan2
- C10orf95 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 179/753 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs1277965531; called by muse, mutect2, varscan2
- COA3 | c.69C>G p.I23M | Missense Mutation (SNP) | VAF 111/499 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs767844043; called by muse, mutect2, varscan2
- CSMD1 | c.4828G>T p.D1610Y (on ENST00000520002; = p.D1609Y on NM_033225.6) | Missense Mutation (SNP) | VAF 119/334 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59337960; called by muse, mutect2, varscan2
- FREM1 | c.4616C>T p.A1539V | Missense Mutation (SNP) | VAF 166/600 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs753002186, COSV101085423; called by muse, mutect2, varscan2
- HSPG2 | c.688G>C p.D230H | Missense Mutation (SNP) | VAF 106/287 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65930332, COSV65930398; called by muse, mutect2, varscan2
- IGSF10 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs540940513, COSV56787992; called by muse, varscan2
- NMS | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 105/362 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.295); catalogued as COSV100966552; called by muse, mutect2, varscan2
- OR8G5 | c.771C>G p.F257L | Missense Mutation (SNP) | VAF 103/318 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV58382094; called by muse, mutect2, varscan2
- ATP1B3 | c.253C>G p.P85A | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CD163 | c.377C>G p.A126G | Missense Mutation (SNP) | VAF 102/318 reads (32%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- OSR1 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 154/401 reads (38%) | called by muse, mutect2, varscan2
- PLIN4 | c.367G>T p.E123* (on ENST00000301286; = p.E138* on NM_001367868.2) | Nonsense Mutation (SNP) | VAF 58/393 reads (15%) | called by muse, mutect2, varscan2
- SYNE1 | c.25738G>A p.D8580N (on ENST00000367255 / NM_182961.4; = p.D8532N on NM_033071.3) | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TSEN54 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 167/634 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- C10orf95 | c.603G>A p.A201= | Silent (SNP) | VAF 179/752 reads (24%) | called by muse, mutect2, varscan2
- MCM9 | c.1425C>T p.L475= | Silent (SNP) | VAF 122/506 reads (24%) | catalogued as rs1487353334; called by muse, mutect2, varscan2
- OR8G5 | c.534C>T p.F178= | Silent (SNP) | VAF 72/188 reads (38%) | called by muse, mutect2, varscan2
- TENT5A | c.426C>T p.L142= | Silent (SNP) | VAF 154/607 reads (25%) | called by muse, mutect2, varscan2
- ZNF578 | c.1392C>T p.F464= | Silent (SNP) | VAF 66/218 reads (30%) | catalogued as COSV69736340; called by muse, mutect2, varscan2
- SLAMF8 | chr1:159840721 G>C | 3'Flank (SNP) | VAF 87/220 reads (40%) | called by muse, mutect2, varscan2
